CCDI case PBBSZG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/fcb4f49d-518a-4fed-a069-eeb796824fa3

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.0 years (3,296 days).

Biospecimens (3 samples)
- Sample 0DG5A4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG5AC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG5AG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
